Gene-level copy-number profile of tumor specimen TCGA-13-0802-01A from TCGA case TCGA-13-0802, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 79.6 years (29,075 days).
Specimen TCGA-13-0802-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.2633d35a-cf95-4ccd-a5f4-8ef7eda15177.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-13-0802-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d96d1000-56d0-4345-afb7-13e180b20844

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 1,797; copy number 2: 14,727; copy number 3: 23,639; copy number 4: 14,669; copy number 5: 2,818; copy number 6: 930; copy number 7: 222; copy number 8: 317; copy number 9: 159; copy number 10: 48; copy number 11: 74; copy number 13: 12; copy number 14: 81; copy number 15: 27; copy number 16: 8; copy number 18: 73; copy number 19: 53; copy number 20: 18; copy number 26: 99; copy number 31: 42.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-13-0802-01): tumor purity 0.91, ploidy 3.24, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:55,999,200–56,216,942, 3 genes: HNF4GP1, AL138997.1, SPATA2P1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,233 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:22,744,395–24,166,374, 11 genes, copy number 8 (within-gene range 3–8): AL035401.1, AL591416.1, RNU6-1060P, AL139231.1, AL133270.1, AL139093.1, SPTLC1P2, AL032822.1, HNRNPA1P58, NRSN1, FO393410.1.
- chr6:26,956,932–27,596,517, 31 genes, copy number 8–9 (within-gene range 3–9): LINC00240, AL133255.1, AL590062.1, VN1R12P, VN1R13P, VN1R11P, RNU2-62P, AL021807.1, H2BC11, H2AC11, H4C9, H2BC12, H2AC12, MIR3143, RPL10P2, PRSS16, AL021808.1, POM121L2, VN1R10P, ZNF204P, ZNF391, AL031118.1, MCFD2P1, ZNF184, AL021918.4, AL021918.5, AL021918.3, AL021918.2, AL021918.1, CD83P1, RNU6-471P.
- chr6:31,462,728–33,009,591, 142 genes, copy number 8–18 (broad region; genes not listed).
- chr6:33,867,506–34,426,071, 15 genes, copy number 7 (within-gene range 3–7): LINC01016, AL138889.2, AL138889.1, MIR7159, MIR1275, GRM4, KRT18P9, CYCSP55, HMGA1, MIR6835, SMIM29, AL354740.1, RPL35P2, NUDT3, RPS10-NUDT3.
- chr6:36,737,050–41,933,046, 116 genes, copy number 13–26 (broad region; genes not listed).
- chr6:43,011,143–43,852,333, 50 genes, copy number 9: MEA1, KLHDC3, RRP36, AL136304.1, RN7SL403P, CUL7, KLC4, AL355385.2, MRPL2, AL355385.1, PTK7, SRF, CUL9, AL133375.1, DNPH1, TTBK1, SLC22A7, CRIP3, ZNF318, RPL12P47, AL583834.1, RPS2P28, AL590383.1, AL359813.1, AL359813.2, ABCC10, MIR6780B, DLK2, RNU6-1113P, TJAP1, LRRC73, POLR1C, YIPF3, AL355802.3, XPO5, AL355802.1, AL355802.2, POLH, POLH-AS1, GTPBP2, MAD2L1BP, RSPH9, MRPS18A, AL136131.1, AL136131.2, VEGFA, AL136131.3, AL157371.2, LINC02537, AL157371.1.
- chr6:46,220,736–48,214,794, 32 genes, copy number 7: RCAN2, AL359633.1, AL035670.1, CYP39A1, SLC25A27, AL591242.1, TDRD6, PLA2G7, ANKRD66, AL161618.1, MEP1A, ADGRF5, ADGRF5-AS1, ADGRF1, TNFRSF21, B3GNTL1P2, AL451166.1, AL355353.1, CD2AP, Y_RNA, AL358178.1, ADGRF2, ADGRF4, RN7SKP116, AL356421.2, AL356421.1, OPN5, RNU1-105P, PTCHD4, AL353138.1, HNRNPA3P4, RBMXP1.
- chr8:85,107,215–86,561,498, 42 genes, copy number 7 (within-gene range 3–7): LRRCC1, AC011773.4, E2F5, AC011773.1, RBIS, CA13, AC011773.3, AC011773.2, CA1, CA3, CA3-AS1, CA2, AC084734.1, AC093331.1, REXO1L8P, REXO1L3P, REXO1L1P, REXO1L12P, REXO1L11P, REXO1L10P, REXO1L9P, REXO1L2P, AC232323.1, REXO1L4P, REXO1L5P, REXO1L6P, AC100801.1, LINC02849, AC100801.2, ATP6V0D2, AC023194.1, AC023194.2, PSKH2, AC023194.3, AC084128.1, SLC7A13, AC103760.1, WWP1, RMDN1, NTAN1P2, SLC2A3P4, CPNE3.
- chr8:86,593,755–86,594,589, 1 gene, copy number 7: MIOXP1.
- chr8:89,243,401–89,415,071, 2 genes, copy number 8: RPSAP74, KRT8P4.
- chr9:21,929,457–25,089,151, 30 genes, copy number 7–9: ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL161628.1, AL365204.1, AL365204.2, AL365204.3, AL513317.1, IZUMO3, AL353811.1, RMRPP5, RN7SKP120.
- chr10:113,353,425–114,404,756, 25 genes, copy number 10–16: RNU7-165P, AL133482.1, PPIAP39, HABP2, NRAP, CASP7, AL592546.2, PLEKHS1, MIR4483, AL592546.1, DCLRE1A, NHLRC2, AL592546.3, ADRB1, AC022023.2, RNU6-709P, UBE2V1P5, CCDC186, AC022023.1, MIR2110, TDRD1, VWA2, AURKAP2, AC005383.1, AFAP1L2.
- chr11:69,294,151–73,598,189, 147 genes, copy number 8 (within-gene range 6–8) (broad region; genes not listed).
- chr13:31,739,526–32,538,885, 16 genes, copy number 7–10 (within-gene range 6–10): RXFP2, AL138708.1, FRY, EEF1DP3, AC002525.1, Metazoa_SRP, FRY-AS1, ZAR1L, BRCA2, IFIT1P1, N4BP2L1, AL137247.1, AL137247.2, N4BP2L2, ATP8A2P2, N4BP2L2-IT2.
- chr13:82,778,208–84,069,408, 11 genes, copy number 10: AL445255.1, GYG1P2, AL512782.1, RNU6-67P, AL353688.1, SLITRK1, AL355481.1, VENTXP2, AL590681.1, UBE2D3P4, AL445604.1.
- chr13:86,909,586–88,630,397, 20 genes, copy number 7–10 (within-gene range 7–20): LINC00430, UBBP5, LIN28AP2, AL360267.2, AL360267.1, MIR4500HG, AL355578.1, MIR4500, SLITRK5, AL445647.2, LINC00397, AL445647.1, TET1P1, LINC00373, RPL29P29, AL355677.1, LINC00433, AL445984.2, AL445984.1, LINC00560.
- chr13:92,239,835–96,839,562, 49 genes, copy number 7 (within-gene range 6–7): AL157815.1, GPC5-AS2, AL159152.1, GPC5-IT1, MIR548AS, AL356737.2, AL356737.1, GPC5-AS1, LINC00363, AL354811.2, AL354811.1, GPC6, AL160159.1, HNRNPA1P29, GPC6-AS2, RNA5SP35, GPC6-AS1, DCT, TGDS, GPR180, RNA5SP36, LINC00391, RN7SL585P, SOX21-AS1, SOX21, BRD7P5, RPL21P112, LINC00557, AL139381.1, RNU6-62P, ABCC4, RNY3P8, RNY4P27, MEMO1P5, CLDN10, CLDN10-AS1, DZIP1, DNAJC3-DT, DNAJC3, MTND5P2, MTND6P18, MTCYBP3, AL138955.1, UGGT2, HMGN1P24, HS6ST3, RN7SL164P, MIR4501, AMMECR1LP1.
- chr13:104,814,327–114,132,623, 151 genes, copy number 14–31 (within-gene range 3–31) (broad region; genes not listed).
- chr18:66,501,083–80,097,088, 204 genes, copy number 9–15 (within-gene range 4–15) (broad region; genes not listed).
- chr19:38,899,700–40,629,818, 97 genes, copy number 8–19 (within-gene range 3–19) (broad region; genes not listed).
- chr21:27,358,885–29,940,033, 41 genes, copy number 7 (within-gene range 3–7): AP001605.1, AP001604.1, EIF4A1P1, RPL10P1, NCSTNP1, LINC01673, LINC00113, AJ006995.1, LINC00314, LINC01697, LINC01695, AF165147.1, LINC00161, U6, N6AMT1, HSPD1P7, THUMPD1P1, LTN1, RPL23P2, RWDD2B, AF129075.2, USP16, CCT8, AF129075.1, AF129075.3, MAP3K7CL, RPL12P9, Y_RNA, U3, AF124730.1, LINC00189, BACH1, GAPDHP14, BACH1-IT1, AP000240.1, BACH1-AS1, BACH1-IT2, BACH1-IT3, GRIK1, AP000238.1, GRIK1-AS1.

Autosomal genes at a single copy (total copy number 1): 1,767. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
